Somatic mutation profile of tumor specimen TCGA-DU-A6S3-01A (aliquot TCGA-DU-A6S3-01A-12D-A32B-08) from TCGA case TCGA-DU-A6S3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 60.3 years (22,038 days).
Specimen TCGA-DU-A6S3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6f12734-7e24-4317-9bef-da28aafed331.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A6S3-10A (Blood Derived Normal), aliquot TCGA-DU-A6S3-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42198361-a752-4533-b71e-7a29e533c07d

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, In Frame Del 6, Frame Shift Del 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 24/36 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 16/26 reads (62%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.1359_1361del p.E453del | In Frame Del (DEL) | VAF 36/114 reads (32%) | hotspot (GDC flag); catalogued as rs587776933; called by pindel, varscan2
- ARFGEF3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV99293844; called by muse, mutect2, varscan2
- CDH8 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as rs1179259076, COSV100181360, COSV54910550; called by muse, mutect2, varscan2
- DNAI1 | c.1638_1639del p.S547Lfs*33 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs748929117; called by pindel, varscan2
- DTNB | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781462559, COSV56473136; called by muse, mutect2, varscan2
- EFEMP1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs398123542, COSV62617183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHOD1 | c.2536_2538del p.K846del | In Frame Del (DEL) | VAF 17/39 reads (44%) | catalogued as rs1387389175; called by mutect2, pindel, varscan2
- KCNH3 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57792656; called by muse, mutect2, varscan2
- KIFAP3 | c.630T>G p.F210L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100846974; called by muse, mutect2, varscan2
- LRIG1 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1425611577, COSV56236723; called by muse, mutect2, varscan2
- MAP3K8 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.53); catalogued as rs750729733, COSV53921471; called by muse, mutect2, varscan2
- MYH11 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774279707, COSV55562098; ClinVar: uncertain significance; called by muse, mutect2
- OBSCN | c.17900G>A p.R5967H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs529998585, COSV99480197; called by muse, mutect2
- PHC1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV101418636; called by muse, mutect2
- POU5F2 | c.719T>C p.I240T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs754470635, COSV101232805; called by muse, mutect2, varscan2
- PPEF2 | c.517_519del p.E173del | In Frame Del (DEL) | VAF 15/100 reads (15%) | catalogued as rs1376663797; called by pindel, varscan2
- SEMA6D | c.2452C>T p.P818S (on ENST00000316364 / NM_153618.2; = p.P756S on NM_020858.2) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV60375303; called by muse, mutect2, varscan2
- TOP3B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs774264750, COSV64116920; called by muse, mutect2, varscan2
- TRIM27 | c.1026C>A p.Y342* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV101019370; called by muse, mutect2, varscan2
- WDR76 | c.1419T>G p.H473Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV99776469; called by muse, mutect2, varscan2
- FUBP1 | c.1335_1339del p.E445Dfs*44 | Frame Shift Del (DEL) | VAF 21/39 reads (54%) | called by mutect2, pindel, varscan2
- LCP1 | c.982_984del p.K328del | In Frame Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- MPDZ | c.1259del p.G420Efs*10 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- USP5 | c.1543_1545del p.E515del | In Frame Del (DEL) | VAF 19/69 reads (28%) | called by pindel, varscan2
- BDKRB2 | c.393C>T p.R131= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as rs1406587452, COSV60013654; called by muse, mutect2, varscan2
- CABP2 | c.504G>A p.G168= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1017085785, COSV99590836; called by muse, mutect2, varscan2
- HMCN1 | c.5367A>G p.K1789= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as COSV99630740; called by muse, mutect2, varscan2
- SCN2A | c.645G>A p.A215= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs370724112, COSV51833008, COSV51835837; called by muse, mutect2, varscan2
- SLC6A20 | c.1456C>T p.L486= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100653765; called by muse, mutect2, varscan2
- TPRX1 | c.1017T>C p.D339= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100445753; called by muse, mutect2, varscan2
- NACA | c.71-2382_71-2380del | Intron (DEL) | VAF 9/36 reads (25%) | catalogued as rs772924203; called by pindel, varscan2
